Surgical pathology report (de-identified scan), TCGA case TCGA-IG-A3YC, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Asterand, specimen TCGA-IG-A3YC-01A (Primary Tumor).

Path Report: ESOPHAGUS TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Esophagus *Distal, per TSS.*

Tumor size: 2.5 x 2 x 2 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Adventitia

Lymph nodes: 1/5 positive for metastasis (Intraabdominal 1/5)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3

*Carcinoma, squamous cell, NOS
8070/3*

Site:

*CQCF - esophagus, distal third
C15.5*

*path - esophagus, NOS
C15.9 41412
R0*

W Skunk

Source: NCI Genomic Data Commons file 76f5d0da-037f-4f8c-bebf-d1dc83ef33dd (TCGA-IG-A3YC.D21ECE97-1A52-48F0-AE8D-34D556DBE08F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).